Somatic mutation profile of tumor specimen MP2PRT-PAVJEF-TMP1-A (aliquot MP2PRT-PAVJEF-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVJEF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.6 years (3,522 days).
Specimen MP2PRT-PAVJEF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c01d44b-1078-4671-ba31-6ad9eb58211b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVJEF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVJEF-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4675b13-78f8-431c-8b9e-3c807d233421

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Frame Shift Ins 1, Intron 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALB | c.79C>T p.H27Y | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs141733599, CM940018; ClinVar: other; called by muse, mutect2, varscan2
- DCAF12L1 | c.1210C>A p.L404I | Missense Mutation (SNP) | VAF 222/564 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100948372; called by muse, mutect2, varscan2
- FAM189A2 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 149/296 reads (50%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.931); catalogued as rs746650154, COSV57383680, COSV57383964; called by muse, mutect2, varscan2
- KRT85 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 253/785 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57736211; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 102/371 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRDM9 | c.500T>A p.L167Q | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs372646164; called by muse, mutect2, varscan2
- PSTPIP2 | c.630C>G p.I210M | Missense Mutation (SNP) | VAF 16/303 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.577); catalogued as COSV99065743; called by muse, mutect2
- RUNX1T1 | c.1176G>T p.W392C (on ENST00000265814 / NM_001198628.1; = p.W365C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 174/479 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56159706; called by muse, mutect2, varscan2
- AGAP2 | c.2947G>A p.V983I (on ENST00000547588 / NM_001122772.2; = p.V627I on NM_014770.4) | Missense Mutation (SNP) | VAF 251/626 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- ARMCX3 | c.1050A>G p.I350M | Missense Mutation (SNP) | VAF 38/406 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- FAM186A | c.5836A>G p.S1946G | Missense Mutation (SNP) | VAF 42/383 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLG1 | c.2079G>A p.M693I | Missense Mutation (SNP) | VAF 100/288 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IRF1 | c.549_552dup p.P185Vfs*25 | Frame Shift Ins (INS) | VAF 16/193 reads (8%) | called by mutect2, pindel
- PHKA2 | c.3653C>A p.A1218E | Missense Mutation (SNP) | VAF 259/673 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PRKDC | c.11668_11671del p.M3890Vfs*20 | Frame Shift Del (DEL) | VAF 111/302 reads (37%) | called by mutect2, pindel, varscan2
- PTGER3 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 34/524 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- VWA1 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 307/780 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- NAV3 | c.4032C>T p.L1344= | Silent (SNP) | VAF 132/401 reads (33%) | called by muse, mutect2, varscan2
- DST | c.4297-3956G>A | Intron (SNP) | VAF 132/375 reads (35%) | called by muse, mutect2, varscan2
